Somatic mutation profile of tumor specimen TCGA-95-7562-01A (aliquot TCGA-95-7562-01A-11D-2238-08) from TCGA case TCGA-95-7562, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.2 years (26,000 days).
Specimen TCGA-95-7562-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b2866bb-5427-439d-b155-37542e596c48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-7562-10B (Blood Derived Normal), aliquot TCGA-95-7562-10B-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/897fa266-afac-4ab7-90d0-5046444486fc

The open-access MAF lists 439 somatic variants for this specimen: 361 protein-altering or splice-affecting, 67 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 292, Silent 67, Nonsense Mutation 24, In Frame Del 18, Frame Shift Del 14, Splice Site 8, Frame Shift Ins 3, RNA 3, Intron 3, 3'UTR 2, Splice Region 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 22/38 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 19/78 reads (24%) | hotspot (GDC flag); called by pindel, varscan2
- TP53 | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 168/282 reads (60%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2, varscan2
- ABCB6 | c.641A>G p.Y214C | Missense Mutation (SNP) | VAF 67/102 reads (66%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs1269067056, COSV99521419; called by muse, mutect2, varscan2
- AC011455.2 | c.651G>T p.K217N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.349); catalogued as COSV99671063; called by muse, mutect2, varscan2
- ADAMTS1 | c.1487C>A p.S496Y | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.79); PolyPhen benign (0.399); catalogued as COSV99535774; called by muse, mutect2, varscan2
- ADAMTS9 | c.4472G>C p.R1491T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV55777396, COSV99898529; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4021A>T p.S1341C | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV99716572; called by muse, mutect2, varscan2
- ADGRA3 | c.3881G>C p.S1294T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV51562545, COSV99292839; called by muse, mutect2, varscan2
- ADORA2A | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs199666600; called by muse, mutect2, varscan2
- AEBP1 | c.1529A>T p.E510V | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV99788323; called by muse, mutect2, varscan2
- AGO3 | c.614A>T p.Q205L | Missense Mutation (SNP) | VAF 322/621 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99867857; called by muse, mutect2, varscan2
- AHNAK | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99945283; called by muse, mutect2, varscan2
- AHNAK2 | c.7654C>T p.P2552S | Missense Mutation (SNP) | VAF 95/773 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs532347726, COSV100315193; called by muse, mutect2, varscan2
- AHNAK2 | c.5185G>T p.G1729C | Missense Mutation (SNP) | VAF 110/525 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100315196; called by muse, mutect2, varscan2
- AKAP12 | c.2006C>A p.P669Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99482235; called by muse, mutect2, varscan2
- ALPI | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 60/78 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99785648; called by muse, mutect2, varscan2
- ANGEL1 | c.285G>T p.M95I | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.878); catalogued as COSV51871864, COSV99200296; called by muse, mutect2, varscan2
- ANKRD44 | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as COSV99983867; called by muse, mutect2, varscan2
- APBA2 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 99/187 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68790652, COSV68793530; called by muse, mutect2, varscan2
- ARHGAP32 | c.1754C>T p.P585L (on ENST00000310343 / NM_001378025.1; = p.P236L on NM_014715.4) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100086726; called by muse, mutect2, varscan2
- ASL | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 80/144 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs755245694, COSV59188852; called by muse, mutect2, varscan2
- ASPM | c.7426_7428del p.K2476del | In Frame Del (DEL) | VAF 23/136 reads (17%) | catalogued as rs750568990; called by pindel, varscan2
- ASTN1 | c.1804C>G p.R602G | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56065747, COSV99029663, COSV99920176; called by muse, mutect2, varscan2
- ASTN1 | c.847G>T p.G283W | Missense Mutation (SNP) | VAF 143/316 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as rs774932385, COSV56060988, COSV56083406; called by muse, mutect2, varscan2
- ASXL3 | c.4750C>A p.R1584S | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as COSV52462370, COSV99322987; called by muse, varscan2
- BNIP3L | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.185); catalogued as COSV101019940; called by muse, mutect2, varscan2
- BRD2 | c.687_689del p.P231del | In Frame Del (DEL) | VAF 26/154 reads (17%) | catalogued as rs1418897653; called by pindel, varscan2
- BVES | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV100114602; called by muse, mutect2, varscan2
- C10orf71 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100109579; called by muse, mutect2, varscan2
- C1QTNF2 | c.961T>A p.Y321N (on ENST00000393975; = p.Y276N on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101220796; called by muse, mutect2, varscan2
- C7 | c.1976G>C p.C659S | Missense Mutation (SNP) | VAF 85/144 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759506502, COSV57470081; called by muse, mutect2, varscan2
- C8B | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV64779967; called by muse, mutect2, varscan2
- CACNA1B | c.4958C>T p.T1653M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99494763; called by muse, mutect2, varscan2
- CACNA1E | c.3644G>T p.G1215V | Missense Mutation (SNP) | VAF 46/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100701223; called by muse, mutect2, varscan2
- CCDC180 | c.4612C>G p.P1538A | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV100826515; called by muse, mutect2, varscan2
- CCDC27 | c.1161G>C p.R387S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV99621987; called by muse, mutect2
- CDH19 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 90/124 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV100050680; called by muse, mutect2, varscan2
- CDS2 | c.1205G>T p.R402I | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100986055; called by muse, mutect2, varscan2
- CEP164 | c.3142G>T p.V1048F | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99632415; called by muse, mutect2, varscan2
- CEP250 | c.5528T>C p.L1843P | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178279806, COSV100698699; called by muse, mutect2, varscan2
- CER1 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101097738; called by muse, mutect2, varscan2
- CFAP91 | c.1446G>T p.L482F | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as COSV99846770; called by muse, mutect2, varscan2
- CHAMP1 | c.1378_1380del p.P460del | In Frame Del (DEL) | VAF 44/216 reads (20%) | catalogued as rs782004732; called by mutect2, pindel, varscan2
- CHID1 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV100059312; called by muse, mutect2, varscan2
- CNGB3 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 71/462 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as CM154647, COSV100181056; called by muse, mutect2, varscan2
- CNTD1 | c.602C>A p.P201Q | Missense Mutation (SNP) | VAF 167/259 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100162027, COSV59312896; called by muse, mutect2, varscan2
- CNTNAP2 | c.1238G>T p.S413I | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV62140552; called by muse, mutect2, varscan2
- COL11A1 | c.2098G>T p.G700C | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614689; called by muse, mutect2, varscan2
- COL22A1 | c.3638G>T p.G1213V | Missense Mutation (SNP) | VAF 133/300 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100275818; called by muse, mutect2, varscan2
- COL22A1 | c.1909G>C p.V637L | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.086); catalogued as rs749051506, COSV100275820, COSV100276187; called by muse, mutect2
- COL5A1 | c.4201G>T p.E1401* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100879366, COSV65668107; called by muse, mutect2, varscan2
- COL6A3 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.778); catalogued as rs149330325; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL9A1 | c.2528G>A p.R843H | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs547618159, COSV57888307; called by muse, mutect2, varscan2
- COQ4 | c.779A>T p.H260L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100306583; called by muse, mutect2, varscan2
- CR1 | c.4880G>T p.G1627V | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914840013, COSV100887341; called by muse, mutect2, varscan2
- CRACD | c.2243G>T p.R748I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.693); catalogued as COSV99948411; called by muse, mutect2, varscan2
- CRISP1 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV59993016; called by muse, mutect2, varscan2
- CRLF2 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101053579; called by muse, mutect2, varscan2
- CSN1S1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as rs771114454, COSV55890908, COSV55892440; called by muse, mutect2, varscan2
- CSNK1E | c.695_697del p.K232del | In Frame Del (DEL) | VAF 20/161 reads (12%) | catalogued as rs748988647; called by pindel, varscan2
- CTAG2 | c.234C>A p.C78* | Nonsense Mutation (SNP) | VAF 25/40 reads (63%) | catalogued as COSV99908734; called by muse, mutect2, varscan2
- CYP11B2 | c.580C>G p.H194D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV100010572; called by muse, mutect2, varscan2
- CYP2A13 | c.859T>A p.Y287N | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100386602; called by muse, mutect2, varscan2
- CYP4B1 | c.35_37del p.S12del | In Frame Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs1344545131; called by pindel, varscan2
- CYP4F22 | c.557G>T p.W186L | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99512459; called by muse, mutect2, varscan2
- DCHS1 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100201368; called by muse, mutect2, varscan2
- DEF6 | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100359109; called by muse, mutect2, varscan2
- DFFB | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 37/72 reads (51%) | catalogued as COSV100138595; called by muse, mutect2, varscan2
- DHX30 | c.406G>C p.A136P (on ENST00000445061 / NM_138615.3; = p.A97P on NM_014966.3) | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.583); catalogued as COSV100819880, COSV62393438; called by muse, mutect2
- DLGAP3 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99332067; called by muse, mutect2, varscan2
- DNAH7 | c.10722A>T p.E3574D | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT tolerated (0.59); PolyPhen benign (0.102); catalogued as COSV56774215; called by muse, mutect2, varscan2
- DNAH7 | c.6183G>T p.E2061D | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413590; called by muse, mutect2, varscan2
- DNAI4 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV100925198, COSV64020121; called by muse, mutect2, varscan2
- DNAJC10 | c.1192G>T p.V398F | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV99898821; called by muse, mutect2, varscan2
- DPEP3 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as COSV99262537; called by muse, mutect2, varscan2
- DTX3L | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV99949820; called by muse, mutect2, varscan2
- DUSP19 | c.88A>T p.K30* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV100700189; called by muse, mutect2, varscan2
- DZIP1L | c.825G>T p.W275C | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV100551049; called by muse, mutect2, varscan2
- EDA2R | c.36G>T p.W12C | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV99490466; called by muse, mutect2, varscan2
- EDA2R | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 40/48 reads (83%) | catalogued as rs1388389041, COSV99490468; called by muse, mutect2, varscan2
- EFCAB12 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373478645; called by muse, mutect2, varscan2
- EFCAB7 | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV100937564; called by muse, mutect2, varscan2
- EHD2 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV99621548; called by muse, mutect2, varscan2
- ELAVL4 | c.482C>A p.S161* | Nonsense Mutation (SNP) | VAF 118/259 reads (46%) | catalogued as COSV100836491; called by muse, mutect2, varscan2
- ELN | c.1937G>T p.G646V (on ENST00000320399 / NM_001278939.1; = p.G613V on NM_000501.4) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99332150; called by muse, mutect2, varscan2
- ENPP6 | c.455C>A p.T152N | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99698399; called by muse, mutect2, varscan2
- EPS15L1 | c.558G>T p.V186= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99932618; called by muse, varscan2
- ERBB4 | c.1086C>G p.I362M | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99615104; called by muse, mutect2, varscan2
- ERBB4 | c.886A>T p.N296Y | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53535291, COSV99615107; called by muse, mutect2, varscan2
- ERICH3 | c.3028G>T p.E1010* | Nonsense Mutation (SNP) | VAF 48/91 reads (53%) | catalogued as COSV100443193; called by muse, mutect2, varscan2
- FAM135B | c.4096G>A p.V1366M | Missense Mutation (SNP) | VAF 122/799 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746980035, COSV52725676; called by muse, mutect2, varscan2
- FAM151B | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 107/202 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV99971547; called by muse, mutect2, varscan2
- FANCG | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs955462060, COSV100734066; called by muse, mutect2, varscan2
- FASN | c.1304A>G p.Q435R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs766211253, COSV100147208; called by muse, mutect2, varscan2
- FAT4 | c.14903G>T p.G4968V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100627056; called by muse, mutect2, varscan2
- FBXL17 | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 74/124 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100670331; called by muse, mutect2, varscan2
- FBXW9 | c.75C>G p.D25E | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.439); catalogued as COSV100790269; called by muse, mutect2, varscan2
- FGF23 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 170/293 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV99426184; called by muse, mutect2, varscan2
- FGL2 | c.1204C>G p.R402G | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99592038, COSV99593223; called by muse, mutect2, varscan2
- FLG2 | c.5105C>G p.T1702S | Missense Mutation (SNP) | VAF 286/611 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV101165566; called by muse, mutect2, varscan2
- FLNC | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs763954095, COSV57950419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.4271G>T p.G1424V | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs372668981; called by muse, mutect2, varscan2
- FOXP4 | c.1434G>C p.Q478H (on ENST00000307972 / NM_001012426.1; = p.Q465H on NM_138457.3) | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); catalogued as COSV100332331, COSV100332376; called by muse, mutect2, varscan2
- FPR1 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763461632, COSV100493898; called by muse, mutect2, varscan2
- FRMPD1 | c.412G>T p.V138F | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV100899230; called by muse, mutect2, varscan2
- FSTL5 | c.1087C>A p.H363N | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100051960; called by muse, mutect2, varscan2
- FUT9 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); catalogued as COSV100132887; called by muse, mutect2, varscan2
- GABRB3 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100157844; called by muse, mutect2, varscan2
- GAS7 | c.1015G>T p.A339S (on ENST00000432992 / NM_201433.2; = p.A199S on NM_003644.3) | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0.339); catalogued as rs1295889650, COSV100094271; called by muse, mutect2, varscan2
- GBF1 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV100890272; called by muse, mutect2, varscan2
- GJA8 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 100/211 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM166501, COSV53790907, COSV99569031; called by muse, mutect2, varscan2
- GLP2R | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.112); catalogued as COSV99301468; called by muse, mutect2, varscan2
- GPBP1L1 | c.604T>C p.S202P | Missense Mutation (SNP) | VAF 54/440 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs376805372; called by muse, mutect2, varscan2
- GPRASP1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 122/171 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100850896; called by muse, mutect2, varscan2
- GRIA4 | c.1032C>A p.D344E | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV99228287; called by muse, mutect2, varscan2
- GRM8 | c.2189C>T p.T730I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV58855769; called by muse, mutect2, varscan2
- GRM8 | c.2022C>G p.H674Q | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV100279952, COSV58833723; called by muse, mutect2, varscan2
- GTF2A1 | c.137G>C p.W46S | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99993280; called by muse, mutect2, varscan2
- GTPBP3 | c.1231C>A p.L411M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV100258574; called by muse, mutect2, varscan2
- HBG2 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs36049074, CM910213, COSV100400550; ClinVar: other; called by mutect2, varscan2
- HDGFL2 | c.651G>T p.R217S | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100012058; called by muse, mutect2, varscan2
- HEATR5A | c.1464G>T p.L488F | Missense Mutation (SNP) | VAF 93/637 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101119499; called by muse, mutect2, varscan2
- HECW1 | c.1628A>T p.E543V | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); catalogued as COSV101222620; called by muse, mutect2, varscan2
- HEPACAM2 | c.1279C>A p.P427T (on ENST00000394468 / NM_001039372.4; = p.P415T on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV100506340, COSV59060752; called by muse, mutect2, varscan2
- HS3ST4 | c.1177G>T p.G393W | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100499854; called by muse, mutect2, varscan2
- HSPG2 | c.6010C>A p.R2004S | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as COSV101020332, COSV65975083; called by muse, mutect2, varscan2
- ICA1 | c.955+1G>T p.X319_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99654696; called by muse, mutect2, varscan2
- IFI44 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100877249; called by muse, mutect2, varscan2
- IL1RAPL1 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.36); catalogued as COSV100144748; called by muse, mutect2, varscan2
- INHBA | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV99637016, COSV99637749; called by muse, mutect2, varscan2
- ITGA6 | c.2002G>A p.D668N (on ENST00000442250; = p.D629N on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1380589527, COSV51222363; called by muse, mutect2, varscan2
- JRK | c.215A>T p.N72I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV101401018; called by muse, mutect2, varscan2
- KCNH5 | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100525080; called by muse, mutect2, varscan2
- KDR | c.1636C>T p.H546Y | Missense Mutation (SNP) | VAF 229/639 reads (36%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.993); catalogued as COSV55766712; called by muse, mutect2, varscan2
- KIAA1217 | c.3182G>A p.G1061E | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100286114; called by muse, mutect2, varscan2
- KIAA1958 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 156/500 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1469733579, COSV100515782; called by muse, mutect2, varscan2
- KNL1 | c.5819G>T p.R1940L (on ENST00000346991 / NM_170589.5; = p.R1914L on NM_144508.5) | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.865); catalogued as COSV100705797, COSV61151834; called by muse, mutect2, varscan2
- KPNA5 | c.435+1G>T p.X145_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100706049; called by muse, mutect2, varscan2
- LAMA2 | c.5224G>T p.D1742Y | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV101369858; called by muse, mutect2, varscan2
- LAMB3 | c.3157C>T p.Q1053* | Nonsense Mutation (SNP) | VAF 24/310 reads (8%) | catalogued as COSV99151629; called by muse, mutect2
- LGI2 | c.1344G>T p.W448C | Missense Mutation (SNP) | VAF 121/344 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101180734; called by muse, mutect2, varscan2
- LILRA1 | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV99251692; called by muse, varscan2
- LILRB4 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206034647, COSV99553444; called by muse, mutect2, varscan2
- LMNTD2 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV99529337; called by muse, mutect2, varscan2
- LMX1A | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.114); catalogued as rs566442201, COSV99671508; called by muse, mutect2, varscan2
- LPA | c.2899A>G p.M967V | Missense Mutation (SNP) | VAF 395/1091 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.682); catalogued as COSV100305906; called by muse, mutect2, varscan2
- LRBA | c.6476A>T p.N2159I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100840836; called by muse, mutect2, varscan2
- LRP1B | c.2791C>G p.Q931E | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.412); catalogued as COSV101250964; called by muse, mutect2, varscan2
- LRRN2 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 75/149 reads (50%) | catalogued as COSV100912721, COSV104425402; called by muse, mutect2, varscan2
- LTBP2 | c.3428A>G p.Q1143R | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV99999523; called by muse, mutect2, varscan2
- LVRN | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.656); catalogued as COSV100773290; called by muse, mutect2, varscan2
- LYST | c.8687T>A p.L2896H | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV101087890; called by muse, mutect2, varscan2
- MACF1 | c.11167G>T p.E3723* (on ENST00000372915; = p.E1656* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as COSV99240714; called by muse, mutect2, varscan2
- MAGEB18 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV57463892, COSV99082037; called by muse, mutect2, varscan2
- MAGEC1 | c.3097G>T p.E1033* | Nonsense Mutation (SNP) | VAF 54/88 reads (61%) | catalogued as COSV99594692; called by muse, mutect2, varscan2
- MAP3K21 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 27/130 reads (21%) | catalogued as COSV100786065; called by muse, mutect2, varscan2
- MAP3K21 | c.1577A>G p.Q526R | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs906376256, COSV100786066; called by muse, mutect2, varscan2
- MAPKBP1 | c.115-1G>T p.X39_splice | Splice Site (SNP) | VAF 41/70 reads (59%) | catalogued as COSV99528807; called by muse, mutect2, varscan2
- MED12L | c.5716-1G>T p.X1906_splice | Splice Site (SNP) | VAF 67/181 reads (37%) | catalogued as COSV99851205; called by muse, mutect2, varscan2
- MEGF10 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99174672; called by muse, mutect2, varscan2
- MGAT5B | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 33/52 reads (63%) | catalogued as COSV100047128, COSV100049074; called by muse, mutect2, varscan2
- MIOS | c.1108T>C p.C370R | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.593); catalogued as COSV100402510; called by muse, mutect2, varscan2
- MMP15 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99539208; called by muse, mutect2, varscan2
- MMS22L | c.1961G>C p.S654T | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV99245954; called by muse, mutect2, varscan2
- MROH2B | c.561C>A p.F187L | Missense Mutation (SNP) | VAF 226/312 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.164); catalogued as COSV101270439; called by muse, mutect2, varscan2
- MS4A13 | c.402G>A p.L134= | Splice Region (SNP) | VAF 44/93 reads (47%) | catalogued as rs752861141, COSV100981010; called by muse, mutect2, varscan2
- MS4A3 | c.389C>A p.T130K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV99614412; called by muse, mutect2, varscan2
- MUC16 | c.39446C>A p.T13149N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.063); catalogued as rs370076236; called by muse, mutect2, varscan2
- MUC16 | c.24622G>T p.G8208W | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV101197708; called by muse, mutect2, varscan2
- MVP | c.2678G>C p.R893P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV100651458, COSV62421507; called by muse, mutect2, varscan2
- MXRA5 | c.1659C>A p.Y553* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99475486; called by muse, varscan2
- MYH7 | c.4203G>T p.E1401D | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100805616; called by muse, mutect2, varscan2
- MYLPF | c.169A>G p.M57V | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100362947; called by muse, mutect2, varscan2
- MYO1B | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100268483; called by muse, mutect2
- MYO1E | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV55691403, COSV99894064; called by muse, mutect2, varscan2
- NBAS | c.6944A>T p.H2315L | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV99866708; called by muse, mutect2, varscan2
- NBEA | c.8224G>T p.G2742* | Nonsense Mutation (SNP) | VAF 69/133 reads (52%) | catalogued as COSV100076171, COSV59790693; called by muse, mutect2, varscan2
- NBEAL2 | c.5557G>T p.E1853* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99434105; called by muse, mutect2, varscan2
- NDC1 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV99323220; called by muse, mutect2, varscan2
- NDST4 | c.1219C>A p.L407M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV52138947; called by muse, mutect2, varscan2
- NEFM | c.1978C>G p.P660A | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99646887; called by muse, varscan2
- NID2 | c.2956C>A p.P986T | Missense Mutation (SNP) | VAF 91/140 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.158); catalogued as COSV99355822; called by muse, mutect2, varscan2
- NLRP12 | c.938G>T p.C313F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV100144751, COSV99048028; called by muse, mutect2, varscan2
- NLRP8 | c.2073G>T p.W691C | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.827); catalogued as COSV99404576; called by muse, mutect2, varscan2
- NPC1L1 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs770897966, COSV56923717, COSV56924298; called by muse, mutect2, varscan2
- NRXN2 | c.3452C>A p.T1151K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV99632194; called by muse, mutect2, varscan2
- OBSCN | c.9184G>C p.V3062L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.05); catalogued as COSV99471463; called by muse, mutect2, varscan2
- OGDHL | c.2420A>T p.Q807L | Missense Mutation (SNP) | VAF 198/434 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100934172; called by muse, mutect2, varscan2
- OR11H4 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 120/713 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100197353; called by muse, mutect2, varscan2
- OR2G6 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as rs1433666370, COSV100598004; called by muse, mutect2, varscan2
- OR2L13 | c.70A>T p.I24L | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100813646; called by muse, mutect2, varscan2
- OR2L2 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.893); catalogued as rs199687835, COSV100823015; called by muse, mutect2, varscan2
- OR2T1 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100822239; called by muse, mutect2, varscan2
- OR2W3 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 64/305 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV100831577; called by muse, mutect2, varscan2
- OR2Z1 | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100136311; called by muse, mutect2
- OR4C15 | c.266C>A p.A89E (on ENST00000314644; = p.A35E on NM_001001920.2) | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV100115314; called by muse, mutect2, varscan2
- OR4C46 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.05); catalogued as rs748963606, COSV100060364, COSV60221609; called by muse, mutect2, varscan2
- OR4K13 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 47/514 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100237618; called by muse, mutect2
- OR5H1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 107/394 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV100641606; called by muse, mutect2, varscan2
- OR6A2 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100215569; called by muse, mutect2, varscan2
- OR6K3 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV100933819; called by muse, mutect2, varscan2
- OR7A5 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.248); catalogued as rs753024227, COSV100457582; called by muse, mutect2, varscan2
- OR8G1 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); catalogued as COSV100422187, COSV58380253; called by muse, mutect2, varscan2
- OR8U1 | c.679A>T p.R227W | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100163706; called by muse, varscan2
- OTOGL | c.6893C>A p.P2298Q (on ENST00000547103; = p.P2289Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086518; called by muse, varscan2
- P2RY8 | c.125T>A p.L42H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.87); catalogued as COSV101183927; called by muse, mutect2, varscan2
- PADI4 | c.1339C>A p.L447M | Missense Mutation (SNP) | VAF 84/164 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100966668; called by muse, mutect2, varscan2
- PAEP | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99478825; called by muse, mutect2, varscan2
- PALB2 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.584); catalogued as rs864622411, COSV99847944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARP15 | c.1867G>A p.G623R (on ENST00000464300 / NM_001113523.3; = p.G389R on NM_152615.2) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100116929, COSV100117033; called by muse, mutect2, varscan2
- PCDHA1 | c.215G>T p.R72M | Missense Mutation (SNP) | VAF 133/187 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV100974243, COSV65372656; called by muse, mutect2, varscan2
- PCDHB12 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99506590; called by muse, mutect2, varscan2
- PCDHB15 | c.55_57del p.L21del | In Frame Del (DEL) | VAF 10/86 reads (12%) | catalogued as rs1448639694; called by pindel, varscan2
- PCDHB6 | c.1020C>A p.D340E | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99169893; called by muse, mutect2, varscan2
- PCDHB8 | c.894G>T p.L298F | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.014); catalogued as COSV99175315; called by muse, mutect2, varscan2
- PDE4D | c.1979G>T p.C660F (on ENST00000340635 / NM_001104631.2; = p.C524F on NM_006203.4) | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100401298; called by muse, mutect2, varscan2
- PDLIM5 | c.214G>C p.G72R | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV100523263; called by muse, mutect2, varscan2
- PDZRN3 | c.1174T>A p.S392T | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV99726935; called by muse, mutect2, varscan2
- PI4KA | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs150004135, COSV99743945; called by muse, mutect2, varscan2
- PIK3C3 | c.2183G>C p.S728T | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV100010129; called by muse, mutect2, varscan2
- PIP4P2 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 80/684 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as rs758488670, COSV99575083; called by muse, mutect2, varscan2
- PKHD1 | c.8141G>T p.R2714L | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61878560; called by muse, mutect2, varscan2
- PKHD1 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs758984026, COSV100580815; called by muse, mutect2, varscan2
- PKHD1L1 | c.3491C>A p.S1164Y | Missense Mutation (SNP) | VAF 190/520 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1370634074, COSV101005169; called by muse, mutect2, varscan2
- PKHD1L1 | c.5491C>A p.P1831T | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.855); catalogued as COSV101005170; called by muse, mutect2, varscan2
- PKHD1L1 | c.5492C>G p.P1831R | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as COSV101005171, COSV65753827; called by muse, mutect2, varscan2
- PLG | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 92/302 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM068074, COSV51982818, COSV99804791; called by muse, mutect2, varscan2
- PLXNB1 | c.2897G>T p.R966L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99602124; called by muse, mutect2
- PREX2 | c.3036G>C p.R1012S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99904529; called by muse, mutect2, varscan2
- PRF1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV100942507; called by muse, mutect2, varscan2
- PRR27 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV60641677; called by muse, mutect2, varscan2
- PTPN21 | c.221A>T p.Q74L | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100161396; called by muse, mutect2, varscan2
- PXDNL | c.1896G>T p.L632F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV100680704; called by muse, varscan2
- RALYL | c.55A>T p.I19F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV101568964; called by muse, mutect2
- RASGRP4 | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53093929, COSV99498369; called by muse, mutect2, varscan2
- RB1 | c.2118T>A p.C706* | Nonsense Mutation (SNP) | VAF 44/86 reads (51%) | catalogued as CM0910364, COSV99922777; called by muse, mutect2, varscan2
- RB1CC1 | c.2344G>A p.V782I | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99205361; called by muse, mutect2, varscan2
- RBFOX1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs139251660, COSV60977899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REG1B | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100521245; called by muse, mutect2, varscan2
- RELN | c.7480G>T p.G2494* | Nonsense Mutation (SNP) | VAF 110/231 reads (48%) | catalogued as COSV59021790; called by muse, mutect2, varscan2
- REPIN1 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV101262570; called by muse, mutect2, varscan2
- REST | c.2927C>T p.P976L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV100470609; called by muse, mutect2, varscan2
- REXO5 | c.1070G>T p.C357F | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV99758885; called by muse, mutect2, varscan2
- RFFL | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV99265119; called by muse, mutect2, varscan2
- RHBDF2 | c.1104C>A p.H368Q | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100489138; called by muse, mutect2, varscan2
- ROBO2 | c.2611G>A p.V871I | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.036); catalogued as COSV100163699; called by muse, mutect2, varscan2
- RPS6KA6 | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99423967; called by muse, mutect2, varscan2
- RSF1 | c.2508G>T p.K836N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100406810; called by muse, mutect2, varscan2
- S100A12 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV64199228; called by muse, mutect2, varscan2
- SALL1 | c.429C>A p.S143R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV99171499; called by muse, mutect2, varscan2
- SAXO2 | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100255531; called by muse, mutect2, varscan2
- SCN11A | c.3546G>C p.L1182F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100180751; called by muse, mutect2, varscan2
- SCN9A | c.989G>T p.C330F | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100311066; called by muse, mutect2, varscan2
- SEMA5B | c.602C>A p.T201N | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99530580; called by muse, mutect2, varscan2
- SERTAD4 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100882577; called by muse, mutect2, varscan2
- SEZ6L | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as rs756013990, COSV50667500, COSV99961160; called by muse, mutect2, varscan2
- SH3D19 | c.2111A>T p.Q704L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV100455483; called by muse, mutect2, varscan2
- SH3RF3 | c.1630C>A p.L544M | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.702); catalogued as COSV100512220; called by muse, mutect2, varscan2
- SIRPA | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.184); catalogued as COSV100604973; called by muse, mutect2, varscan2
- SLC22A5 | c.67_69del p.F23del | In Frame Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs377767444; called by pindel, varscan2
- SLC2A2 | c.1285C>G p.Q429E | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100049026; called by muse, mutect2, varscan2
- SLC45A1 | c.566A>G p.H189R | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV99238219; called by muse, mutect2, varscan2
- SLC6A1 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99822325; called by muse, mutect2, varscan2
- SLC6A15 | c.1303G>C p.A435P | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs776914896, COSV99880033; called by muse, mutect2, varscan2
- SLC8A2 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 48/139 reads (35%) | catalogued as COSV99369573; called by muse, mutect2, varscan2
- SLCO1B3 | c.1971G>T p.K657N | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99680646; called by muse, mutect2, varscan2
- SNAP91 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV99534097; called by muse, mutect2, varscan2
- SNX20 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1177671229, COSV100319071; called by muse, mutect2, varscan2
- SPAG16 | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99793326; called by muse, mutect2, varscan2
- SPATA31D1 | c.494C>A p.A165E | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV100782417, COSV61196507; called by muse, mutect2, varscan2
- SPEG | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100403086; called by muse, mutect2, varscan2
- SRRM4 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); catalogued as COSV99937551; called by muse, mutect2
- SRRT | c.2276G>T p.R759L | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53814860, COSV99573665; called by muse, mutect2, varscan2
- STOX2 | c.2087A>G p.E696G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100408269; called by muse, mutect2
- STRN | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99814877; called by muse, mutect2, varscan2
- STXBP5L | c.2084C>A p.P695H | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99871621; called by muse, mutect2, varscan2
- SULT1A1 | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV100131445; called by muse, mutect2, varscan2
- SULT2B1 | c.943G>C p.E315Q (on ENST00000201586 / NM_177973.2; = p.E300Q on NM_004605.2) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV99572014; called by muse, mutect2, varscan2
- SYCP2 | c.1854G>T p.W618C | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100697907, COSV100697939; called by muse, mutect2, varscan2
- TAS1R2 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64744825, COSV64745499; called by muse, mutect2, varscan2
- TBC1D14 | c.314G>T p.C105F | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV101298706; called by muse, mutect2, varscan2
- TENM3 | c.7995G>T p.Q2665H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV101304730, COSV69308490; called by muse, mutect2, varscan2
- TGFB1 | c.873_875del p.K291del | In Frame Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs774427089; called by pindel, varscan2
- THOP1 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV100310330; called by muse, mutect2, varscan2
- THSD7A | c.783C>A p.S261R | Missense Mutation (SNP) | VAF 77/125 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV101448512, COSV70271179; called by muse, mutect2, varscan2
- TLL1 | c.1379C>G p.A460G | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV50282870, COSV50322740; called by muse, mutect2, varscan2
- TLR9 | c.1466C>A p.P489Q | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs770483581, COSV100645526; called by muse, mutect2, varscan2
- TMEM260 | c.1778+1G>T p.X593_splice | Splice Site (SNP) | VAF 76/310 reads (25%) | catalogued as COSV99839921; called by muse, mutect2, varscan2
- TMEM74 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs746023834; called by muse, mutect2
- TMUB1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99879491; called by muse, mutect2, varscan2
- TNNI3K | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 251/498 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100435326; called by muse, mutect2, varscan2
- TNNT3 | c.804G>T p.W268C (on ENST00000397301 / NM_001367846.1; = p.W257C on NM_006757.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53487351, COSV99547821; called by muse, mutect2, varscan2
- TNRC6A | c.1438A>T p.T480S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100169324; called by muse, mutect2, varscan2
- TPX2 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100301464; called by muse, mutect2, varscan2
- TRIM55 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99396436; called by muse, mutect2, varscan2
- TRO | c.3389G>T p.G1130V | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51499119, COSV99435632; called by muse, mutect2, varscan2
- TRPS1 | c.447G>T p.E149D (on ENST00000220888 / NM_001330599.2; = p.E162D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV99627895; called by muse, mutect2
- TSHR | c.555C>A p.Y185* | Nonsense Mutation (SNP) | VAF 37/160 reads (23%) | catalogued as COSV99990862; called by muse, mutect2, varscan2
- TSNAXIP1 | c.493_495del p.E165del | In Frame Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs754888426; called by pindel, varscan2
- TTLL7 | c.2530T>A p.W844R | Missense Mutation (SNP) | VAF 142/266 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); catalogued as COSV99551705; called by muse, mutect2, varscan2
- UACA | c.785-1G>A p.X262_splice | Splice Site (SNP) | VAF 24/39 reads (62%) | catalogued as COSV100537196, COSV100537507; called by muse, mutect2, varscan2
- UGT3A2 | c.833C>A p.P278Q | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV56928518, COSV99235933; called by muse, mutect2
- USP10 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV99551039; called by muse, mutect2
- USP6 | c.570C>A p.S190R | Missense Mutation (SNP) | VAF 131/220 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV100002835; called by muse, mutect2, varscan2
- VN1R2 | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as COSV100447752; called by muse, mutect2, varscan2
- WDR17 | c.1834G>T p.V612L | Missense Mutation (SNP) | VAF 82/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99706583; called by muse, mutect2, varscan2
- WDR49 | c.898+1G>T p.X300_splice (on ENST00000308378 / NM_001366158.1; = p.X641_splice on NM_001348951.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100391380; called by muse, mutect2, varscan2
- WRN | c.1901G>T p.G634V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99988152; called by muse, mutect2, varscan2
- XCR1 | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100499258, COSV58568820; called by muse, mutect2, varscan2
- ZAN | c.3128G>T p.R1043L | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.155); catalogued as rs1040143692, COSV100769030; called by muse, varscan2
- ZCCHC12 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV59572937; called by muse, mutect2
- ZFPM2 | c.3365G>T p.R1122L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101022935, COSV65873680; called by muse, mutect2, varscan2
- ZIC1 | c.404C>A p.T135K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV99291399; called by muse, mutect2, varscan2
- ZIC5 | c.1813C>A p.P605T | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV99940490; called by muse, mutect2, varscan2
- ZNF300 | c.1043C>A p.T348N | Missense Mutation (SNP) | VAF 60/86 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1324787707, COSV99199784; called by muse, mutect2, varscan2
- ZNF423 | c.3476G>T p.S1159I (on ENST00000563137 / NM_001379286.1; = p.S1151I on NM_015069.4) | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV52191068, COSV99279403; called by muse, mutect2, varscan2
- ZNF479 | c.1488A>T p.E496D | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV100482401; called by muse, mutect2, varscan2
- ZNF536 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1309184035, COSV100834521, COSV100835689; called by muse, mutect2, varscan2
- ZNF608 | c.3256G>T p.G1086W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100100820; called by muse, mutect2, varscan2
- ZNF648 | c.1581C>A p.N527K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs758323060, COSV100374393, COSV60569535; called by muse, mutect2, varscan2
- ZNF773 | c.1001G>T p.S334I | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.255); catalogued as COSV99989034; called by muse, mutect2, varscan2
- ZNF800 | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs766103575, COSV99757588; called by muse, mutect2, varscan2
- ZNF835 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 95/267 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV73379389; called by muse, mutect2, varscan2
- ZRSR2 | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.245); catalogued as COSV100236544; called by muse, mutect2, varscan2
- ZZZ3 | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100890179; called by muse, mutect2, varscan2
- ACACA | c.6864G>T p.W2288C | Missense Mutation (SNP) | VAF 118/204 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTLA | c.232_234del p.T78del | In Frame Del (DEL) | VAF 40/204 reads (20%) | called by pindel, varscan2
- CCL15 | c.233C>A p.S78Y | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CDRT15 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); called by muse, varscan2
- CNGB3 | c.681del p.A228Pfs*51 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by mutect2, varscan2
- COL6A3 | c.9170_9175del p.A3057_V3058del | In Frame Del (DEL) | VAF 31/47 reads (66%) | called by mutect2, pindel, varscan2
- CPVL | c.952_953del p.L318Afs*6 | Frame Shift Del (DEL) | VAF 40/165 reads (24%) | called by mutect2, pindel, varscan2
- DCAF12 | c.270_272del p.N90del | In Frame Del (DEL) | VAF 14/116 reads (12%) | called by pindel, varscan2
- FMN2 | c.1713_1715del p.L572del | In Frame Del (DEL) | VAF 27/111 reads (24%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.2970G>T p.K990N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- GFPT2 | c.1576_1578del p.E526del | In Frame Del (DEL) | VAF 12/56 reads (21%) | called by pindel, varscan2
- HLA-B | c.325_327del p.Y109del | In Frame Del (DEL) | VAF 39/86 reads (45%) | called by pindel, varscan2
- IGHM | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IL22RA2 | c.141del p.W47Cfs*26 | Frame Shift Del (DEL) | VAF 37/111 reads (33%) | called by mutect2, pindel, varscan2
- MBD2 | c.667_668del p.Q223Efs*11 | Frame Shift Del (DEL) | VAF 31/252 reads (12%) | called by mutect2, pindel, varscan2
- MTR | c.1469dup p.Y491Vfs*11 | Frame Shift Ins (INS) | VAF 64/149 reads (43%) | called by mutect2, pindel, varscan2
- NEB | c.17183_17184del p.K5728Rfs*13 | Frame Shift Del (DEL) | VAF 34/176 reads (19%) | called by mutect2, pindel, varscan2
- NOP58 | c.686_688del p.E229del | In Frame Del (DEL) | VAF 31/94 reads (33%) | called by pindel, varscan2
- NOXA1 | c.761_762del p.E254Gfs*4 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | called by pindel, varscan2
- OR4Q3 | c.934dup p.I312Nfs*18 | Frame Shift Ins (INS) | VAF 82/242 reads (34%) | called by mutect2, varscan2
- OR4Q3 | c.939dup p.P314Tfs*16 | Frame Shift Ins (INS) | VAF 66/313 reads (21%) | called by mutect2*, pindel, varscan2*
- OTULIN | c.968del p.P323Hfs*8 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- PARVA | c.604_605delinsT p.R202Sfs*33 | Frame Shift Del (DEL) | VAF 39/134 reads (29%) | called by pindel, varscan2*
- PGM5 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PRAMEF10 | c.965T>A p.L322Q | Missense Mutation (SNP) | VAF 179/850 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RPS6KA5 | c.1342del p.S448Vfs*9 | Frame Shift Del (DEL) | VAF 62/299 reads (21%) | called by mutect2, pindel, varscan2
- SLC26A7 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPDYE3 | c.1589_1590+1del | In Frame Del (DEL) | VAF 23/108 reads (21%) | called by pindel, varscan2
- SUPV3L1 | c.1654_1657del p.D552Ifs*8 | Frame Shift Del (DEL) | VAF 28/216 reads (13%) | called by mutect2, pindel
- SYNE1 | c.8661_8664del p.D2888Pfs*19 (on ENST00000367255 / NM_182961.4; = p.D2895Pfs*19 on NM_033071.3) | Frame Shift Del (DEL) | VAF 55/234 reads (24%) | called by mutect2, pindel, varscan2
- TAF15 | c.294A>T p.Q98H (on ENST00000605844 / NM_139215.3; = p.Q95H on NM_003487.4) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TMPRSS15 | c.1069del p.V357Sfs*4 | Frame Shift Del (DEL) | VAF 31/69 reads (45%) | called by mutect2, pindel, varscan2
- TPTE | c.214G>T p.E72* (on ENST00000618007 / NM_199261.4; = p.E54* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- TRMT1L | c.484_487del p.P163Vfs*4 | Frame Shift Del (DEL) | VAF 31/178 reads (17%) | called by mutect2, pindel, varscan2
- USP34 | c.421_422del p.K141Efs*3 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- ADGRF2 | c.375A>G p.P125= (on ENST00000296862 / NM_001368115.2; = p.P57= on NM_153839.7) | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs1484418817, COSV99730589; called by muse, mutect2, varscan2
- ARHGEF10 | c.3837C>T p.S1279= (on ENST00000398564; = p.S1254= on NM_014629.4) | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as rs764863519, COSV100033547; called by muse, mutect2
- ASXL1 | c.573G>T p.S191= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100037400; called by muse, mutect2, varscan2
- BCAS1 | c.948C>A p.T316= | Silent (SNP) | VAF 87/194 reads (45%) | catalogued as COSV101005991; called by muse, mutect2, varscan2
- BCOR | c.2715G>T p.L905= | Silent (SNP) | VAF 24/39 reads (62%) | catalogued as COSV100652756; called by muse, mutect2, varscan2
- BEND2 | c.2181C>G p.L727= | Silent (SNP) | VAF 72/101 reads (71%) | catalogued as COSV101191722; called by muse, mutect2, varscan2
- CDH20 | c.1992C>T p.R664= | Silent (SNP) | VAF 146/203 reads (72%) | catalogued as COSV99404097; called by muse, mutect2, varscan2
- CITED2 | c.606C>T p.P202= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as COSV100863089; called by muse, mutect2, varscan2
- CRB1 | c.2865T>C p.N955= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as COSV100957622, COSV66334539; called by muse, mutect2, varscan2
- ERICH3 | c.3027G>T p.S1009= | Silent (SNP) | VAF 46/90 reads (51%) | catalogued as COSV100443194; called by muse, mutect2, varscan2
- FGL1 | c.18T>C p.S6= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV67712688, COSV67712711; called by muse, mutect2
- FKBP10 | c.1729C>A p.R577= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV99505008; called by muse, mutect2, varscan2
- GAGE1 | c.276T>C p.P92= | Silent (SNP) | VAF 39/519 reads (8%) | catalogued as rs1557131414, COSV67747829; called by muse, mutect2, varscan2
- GAP43 | c.405C>G p.A135= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV100525233; called by muse, mutect2, varscan2
- GLIPR1 | c.246G>T p.R82= | Silent (SNP) | VAF 76/131 reads (58%) | catalogued as COSV56992597, COSV99875448; called by muse, mutect2, varscan2
- GRIK1 | c.969G>T p.L323= | Silent (SNP) | VAF 42/72 reads (58%) | catalogued as COSV100515682; called by muse, mutect2, varscan2
- GRIN2B | c.1860G>C p.V620= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV101662871, COSV74207113; called by muse, mutect2, varscan2
- ICAM4 | c.105G>A p.K35= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs780823301, COSV99320441; called by muse, varscan2
- IGFLR1 | c.270C>T p.S90= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs765581868, COSV99494867; called by muse, mutect2, varscan2
- IL4R | c.1053C>G p.L351= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV99404603; called by muse, mutect2, varscan2
- IVD | c.339G>T p.L113= (on ENST00000651168; = p.L110= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 59/125 reads (47%) | catalogued as COSV99991328; called by muse, mutect2, varscan2
- JARID2 | c.504G>C p.A168= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100521165; called by muse, mutect2, varscan2
- KALRN | c.4170G>T p.A1390= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as COSV53767620, COSV99561790; called by muse, mutect2, varscan2
- KMO | c.273A>T p.S91= | Silent (SNP) | VAF 205/393 reads (52%) | catalogued as COSV100844766; called by muse, mutect2, varscan2
- KRTAP10-7 | c.42C>T p.S14= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV100169954; called by muse, varscan2
- LAMP5 | c.165G>T p.T55= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as COSV55718304, COSV99855402; called by muse, mutect2, varscan2
- MAGEC2 | c.183G>C p.L61= | Silent (SNP) | VAF 44/66 reads (67%) | catalogued as COSV56001886, COSV99909353; called by muse, varscan2
- MRGPRX3 | c.636C>T p.T212= | Silent (SNP) | VAF 65/109 reads (60%) | catalogued as rs1472248133, COSV101283473; called by muse, mutect2, varscan2
- MS4A15 | c.369C>A p.L123= (on ENST00000405633 / NM_001098835.2; = p.L30= on NM_152717.3) | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV100558813; called by muse, mutect2, varscan2
- MYLK | c.3885C>T p.L1295= | Silent (SNP) | VAF 153/376 reads (41%) | catalogued as COSV100658410; called by muse, mutect2, varscan2
- MYO3A | c.3933C>T p.T1311= | Silent (SNP) | VAF 50/94 reads (53%) | catalogued as rs1311013479, COSV99777910; called by muse, mutect2
- NLRP3 | c.1869C>A p.P623= | Silent (SNP) | VAF 41/72 reads (57%) | catalogued as COSV100275126; called by muse, mutect2, varscan2
- NTRK3 | c.2103C>A p.S701= | Silent (SNP) | VAF 61/122 reads (50%) | catalogued as COSV100712144, COSV62304253; called by muse, mutect2, varscan2
- OR2L2 | c.735T>G p.T245= | Silent (SNP) | VAF 46/222 reads (21%) | catalogued as COSV100823018; called by muse, mutect2, varscan2
- OR2T3 | c.108C>A p.T36= | Silent (SNP) | VAF 29/183 reads (16%) | catalogued as COSV100613022; called by muse, mutect2, varscan2
- OR4K1 | c.456C>T p.G152= | Silent (SNP) | VAF 26/386 reads (7%) | catalogued as rs762768302, COSV53459799; called by muse, mutect2
- OR51A4 | c.813C>A p.P271= | Silent (SNP) | VAF 27/221 reads (12%) | catalogued as COSV100985161, COSV66749412; called by muse, mutect2, varscan2
- OR51G1 | c.156T>C p.C52= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV100429095; called by muse, mutect2
- OR5D18 | c.696C>A p.V232= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV61737108, COSV61738898; called by muse, mutect2, varscan2
- OR6K6 | c.1008G>A p.K336= (on ENST00000368144; = p.K312= on NM_001005184.1) | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as COSV100933661; called by muse, mutect2, varscan2
- PCDH17 | c.480C>T p.D160= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100931384; called by muse, mutect2, varscan2
- PCDHB12 | c.1452C>A p.A484= | Silent (SNP) | VAF 162/249 reads (65%) | catalogued as COSV99506589; called by muse, mutect2, varscan2
- PEG3 | c.3843C>A p.L1281= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV99686878; called by muse, mutect2, varscan2
- PEG3 | c.1995C>T p.T665= | Silent (SNP) | VAF 55/126 reads (44%) | catalogued as COSV55646689, COSV99686882; called by muse, mutect2, varscan2
- PIK3R4 | c.3858A>T p.P1286= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs1337615759, COSV100649698; called by muse, mutect2, varscan2
- PLK1 | c.423G>T p.L141= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100266884; called by muse, mutect2, varscan2
- PPP1R16B | c.1323C>T p.N441= | Silent (SNP) | VAF 62/619 reads (10%) | catalogued as rs1220838748, COSV100240253, COSV55376884; called by muse, mutect2
- PREX2 | c.1734T>C p.L578= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99904527; called by muse, mutect2, varscan2
- PRKG2 | c.1653C>A p.P551= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV100019128; called by muse, mutect2, varscan2
- PSG9 | c.960C>G p.R320= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV99391980; called by muse, mutect2, varscan2
- RHOJ | c.603G>A p.K201= | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as COSV100370019, COSV57460648; called by muse, mutect2, varscan2
- ROBO2 | c.3237C>G p.V1079= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100163701, COSV59930508; called by muse, mutect2, varscan2
- SALL3 | c.2448C>A p.T816= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV101609917; called by muse, mutect2, varscan2
- SIDT1 | c.1377G>T p.V459= | Silent (SNP) | VAF 98/223 reads (44%) | catalogued as COSV99332960, COSV99334982; called by muse, mutect2, varscan2
- SLC22A2 | c.636G>C p.L212= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as COSV100870892; called by muse, mutect2
- SUPT16H | c.315G>C p.L105= | Silent (SNP) | VAF 128/203 reads (63%) | catalogued as COSV99359557; called by muse, mutect2, varscan2
- SYT13 | c.744C>A p.R248= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99194630; called by muse, mutect2, varscan2
- TBCCD1 | c.1503A>T p.I501= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as COSV100111760; called by muse, mutect2, varscan2
- TENM3 | c.636G>A p.R212= | Silent (SNP) | VAF 87/220 reads (40%) | catalogued as COSV69304151; called by muse, mutect2, varscan2
- TEX11 | c.1311A>T p.L437= (on ENST00000344304; = p.L422= on NM_031276.3) | Silent (SNP) | VAF 31/42 reads (74%) | catalogued as COSV100721250; called by muse, mutect2, varscan2
- TFDP2 | c.450G>T p.S150= (on ENST00000489671 / NM_001178139.2; = p.S89= on NM_006286.5) | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as COSV100050627, COSV57713173; called by muse, mutect2, varscan2
- TGIF2LY | c.192C>A p.I64= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100339598; called by muse, mutect2, varscan2
- TRPM1 | c.2109G>T p.L703= | Silent (SNP) | VAF 35/54 reads (65%) | catalogued as COSV99855207; called by muse, mutect2, varscan2
- UMOD | c.1461G>T p.V487= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs543637841, COSV100207934; called by muse, mutect2, varscan2
- ZIC1 | c.627C>A p.G209= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99291400; called by muse, mutect2, varscan2
- ZNF43 | c.15A>G p.T5= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV100731654; called by muse, mutect2, varscan2
- ZNF599 | c.558A>G p.P186= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs1388134172, COSV100250962; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840280 C>A | 5'Flank (SNP) | VAF 32/56 reads (57%) | catalogued as COSV100005069; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83203del | Intron (DEL) | VAF 132/508 reads (26%) | called by mutect2, pindel, varscan2
- ALMS1P1 | chr2:73701116 G>T | 3'Flank (SNP) | VAF 40/57 reads (70%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504770 del TA | 5'Flank (DEL) | VAF 37/96 reads (39%) | catalogued as rs765184061; called by mutect2, pindel, varscan2
- CPLANE1 | c.*3388G>A | 3'UTR (SNP) | VAF 42/54 reads (78%) | catalogued as COSV57068420; called by muse, mutect2, varscan2
- FXYD6P3 | n.100C>A | RNA (SNP) | VAF 29/45 reads (64%) | called by muse, mutect2, varscan2
- KIF2A | c.1647-1172_1647-1170del | Intron (DEL) | VAF 6/23 reads (26%) | called by pindel, varscan2
- NRG1 | c.502+30931G>T | Intron (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99827170, COSV99829337; called by muse, mutect2, varscan2
- OR2W5 | n.731G>T | RNA (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- OSCAR | c.*406C>A | 3'UTR (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99499793, COSV99499919, COSV99500092; called by muse, mutect2, varscan2
- SPATA8 | n.220G>T | RNA (SNP) | VAF 36/84 reads (43%) | catalogued as rs1190371043, COSV60705312; called by muse, mutect2, varscan2
